Somatic mutation profile of tumor specimen TCGA-DJ-A13R-01A (aliquot TCGA-DJ-A13R-01A-11D-A10S-08) from TCGA case TCGA-DJ-A13R, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 50.3 years (18,354 days).
Specimen TCGA-DJ-A13R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6a169f8-ff2a-48b0-8663-168f12abeaf3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A13R-10A (Blood Derived Normal), aliquot TCGA-DJ-A13R-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3df3a00-9314-4f11-9841-adb439667a14

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF2 | c.3007C>T p.Q1003* | Nonsense Mutation (SNP) | VAF 21/95 reads (22%) | catalogued as COSV64211249, COSV64214962; called by muse, mutect2, varscan2
- ARRB1 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs754172924, COSV63574740; called by muse, mutect2, varscan2
- CLCN3 | c.2101C>T p.Q701* | Nonsense Mutation (SNP) | VAF 52/230 reads (23%) | catalogued as COSV61626592; called by muse, mutect2, varscan2
- FADS6 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs145096183, COSV59601801; called by muse, mutect2, varscan2
- FAM50B | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.103); catalogued as COSV66654627; called by muse, mutect2, varscan2
- GALNT16 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs752464899, COSV61885077; called by muse, mutect2, varscan2
- MYH13 | c.5336C>T p.T1779I | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV52822902; called by muse, mutect2, varscan2
- SNX7 | c.697G>T p.V233F | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); catalogued as COSV60266810; called by muse, mutect2, varscan2
- ZC3H13 | c.1150A>G p.R384G | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as COSV54449823; called by muse, mutect2
- IRAK4 | c.858C>T p.H286= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV71210330; called by muse, mutect2, varscan2
- RABL6 | c.1656G>A p.S552= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs781712137, COSV61033991; called by muse, mutect2, varscan2
- SI | c.2988A>T p.T996= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as COSV52270148; called by muse, mutect2, varscan2
